Gene-level copy-number profile of tumor specimen C3N-03792-01 from CPTAC case C3N-03792, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.5 years (14,044 days).
Specimen C3N-03792-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df37692b-802e-4edf-9363-66cf7f339fb6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03792-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/63c67a3f-ba28-43a6-a495-4370840b959e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 8,537; copy number 3: 885; copy number 4: 39,415; copy number 5: 311; copy number 6: 6,491; copy number 7: 310; copy number 8: 2,710; copy number 9: 89; copy number 10: 141; copy number 19: 7; copy number 23: 1; copy number 232: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 240 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,794,880–151,583,583, 48 genes, copy number 9: CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1.
- chr1:151,612,038–151,613,363, 1 gene, copy number 9 (within-gene range 6–9): AL391335.1.
- chr7:35,496,021–35,972,587, 12 genes, copy number 10: AC007652.1, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4.
- chr7:54,542,325–55,260,256, 13 genes, copy number 10–232 (within-gene range 10–234): VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:66,087,761–66,592,397, 20 genes, copy number 10 (within-gene range 8–10): AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1.
- chr7:74,453,790–74,602,605, 1 gene, copy number 10 (within-gene range 8–10): GTF2IRD1.
- chr7:74,606,913–75,994,656, 51 genes, copy number 10: AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1, CCL26, CCL24, AC005102.1, RHBDD2, POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A.
- chr7:152,025,194–152,757,951, 19 genes, copy number 10: Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA, FABP5P3, CCT8L1P, LINC01003, AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P.
- chr19:463,346–1,009,732, 40 genes, copy number 9 (within-gene range 7–9): ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B.
- chr19:4,229,523–4,724,673, 35 genes, copy number 10: EBI3, AC005578.1, YJU2, SHD, TMIGD2, FSD1, STAP2, AC104521.1, MPND, AC007292.3, EIF1P6, AC007292.2, SH3GL1, AC007292.1, CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5, AC011498.4, LRG1, SEMA6B, AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
